Gene-level copy-number profile of tumor specimen ALCH-B3AT-TTP1-A from ALCHEMIST case ALCH-B3AT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.6 years (18,495 days).
Specimen ALCH-B3AT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b8c668f7-5720-45f4-8fe5-f8c0feebfd34.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/ba4a1ea3-eb9b-4679-aa9a-aae383fc3245

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 531; copy number 2: 1,628; copy number 3: 9,767; copy number 4: 36,738; copy number 5: 7,585; copy number 6: 2,408; copy number 7: 73; copy number 8: 35; copy number 10: 115; copy number 18: 7; copy number 25: 1; copy number 35: 1; copy number 37: 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:142,567,260–142,577,881, 1 gene: MROH4P.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr16:32,903,442–32,946,392, 4 genes: IGHV3OR16-15, IGHV3OR16-6, AC142086.6, AC142086.3.
- chr19:45,733,439–45,772,504, 4 genes (within-gene range 0–3): BHMG1, SIX5, AC074212.1, DM1-AS.
- chr21:44,978,832–44,979,274, 1 gene: AP001505.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 126 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,453,030, 7 genes, copy number 18: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr16:32,289,547–32,310,555, 1 gene, copy number 25: AC133548.2.
- chr16:32,869,985–32,888,874, 3 genes, copy number 35–37: BCAP31P2, SLC6A10P, AC142086.1.
- chr20:34,689,097–38,377,013, 115 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
